Somatic mutation profile of tumor specimen 0DODNZ from CCDI case PBCBYB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyoma, NOS; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 16.8 years (6,123 days).
Specimen 0DODNZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59f2617c-1852-4875-aad6-8dee85a0ecd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DODM7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d66090c-77b8-49ce-855e-fe194cd81bb8

The open-access MAF lists 43 somatic variants for this specimen: 21 protein-altering or splice-affecting, 11 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 11, Intron 6, 5'UTR 3, 3'UTR 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG2A | c.5050G>T p.V1684F | Missense Mutation (SNP) | VAF 84/217 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV65968121; called by muse, varscan2
- COL27A1 | c.5323G>A p.E1775K | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs1169563204; called by muse, mutect2, varscan2
- COP1 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 75/301 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV58178653; called by muse, mutect2, varscan2
- DDRGK1 | c.402G>C p.Q134H | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs1477710572; called by muse, mutect2, varscan2
- KCP | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.023); catalogued as rs981064215; called by muse, mutect2, varscan2
- MUC12 | c.2473C>G p.L825V (on ENST00000379442; = p.L682V on NM_001164462.1) | Missense Mutation (SNP) | VAF 38/416 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.374); catalogued as rs753968102; called by muse, varscan2
- OR1E1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 89/208 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59459154; called by muse, mutect2, varscan2
- PLOD3 | c.1970G>A p.R657Q | Missense Mutation (SNP) | VAF 57/249 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as rs750040825; called by muse, mutect2, varscan2
- VCAN | c.9584G>A p.R3195Q | Missense Mutation (SNP) | VAF 108/362 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145625752; called by muse, mutect2, varscan2
- ADAM8 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CILP2 | c.1993G>A p.V665M | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CTTNBP2 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 96/636 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- FAM47A | c.2130T>G p.S710R | Missense Mutation (SNP) | VAF 94/103 reads (91%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- HSPA1L | c.37C>A p.L13M | Missense Mutation (SNP) | VAF 111/195 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRFN5 | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 107/284 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NRCAM | c.1289A>G p.Y430C (on ENST00000379028 / NM_001371124.1; = p.Y424C on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 107/622 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHF3 | c.231G>T p.M77I | Missense Mutation (SNP) | VAF 72/178 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by mutect2, varscan2
- PRB4 | c.551A>C p.Q184P | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- PRPS1L1 | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 92/569 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SVEP1 | c.2602C>G p.P868A | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UGT1A4 | c.85G>T p.G29* | Nonsense Mutation (SNP) | VAF 143/272 reads (53%) | called by muse, mutect2, varscan2
- ASB12 | c.549C>T p.G183= | Silent (SNP) | VAF 30/34 reads (88%) | catalogued as rs767310102, COSV100744853, COSV100744888; called by muse, mutect2, varscan2
- COQ4 | c.321A>T p.T107= | Silent (SNP) | VAF 119/239 reads (50%) | called by muse, mutect2, varscan2
- CRYBG2 | c.672C>T p.S224= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as rs1480999393; called by muse, mutect2, varscan2
- LRRC56 | c.603G>A p.P201= | Silent (SNP) | VAF 56/272 reads (21%) | catalogued as rs375900126; called by muse, mutect2, varscan2
- REXO1 | c.3564C>T p.I1188= | Silent (SNP) | VAF 40/89 reads (45%) | called by muse, mutect2, varscan2
- RIN1 | c.310C>T p.L104= | Silent (SNP) | VAF 60/247 reads (24%) | called by muse, mutect2, varscan2
- RNF112 | c.543G>A p.G181= | Silent (SNP) | VAF 73/156 reads (47%) | called by muse, mutect2, varscan2
- SIRPB1 | c.1134C>A p.G378= | Silent (SNP) | VAF 114/381 reads (30%) | called by muse, mutect2, varscan2
- SSC5D | c.693C>T p.D231= | Silent (SNP) | VAF 40/79 reads (51%) | catalogued as rs777436474, COSV99220353; called by muse, varscan2
- TENM4 | c.501G>A p.P167= | Silent (SNP) | VAF 38/144 reads (26%) | called by muse, mutect2, varscan2
- ZMYM2 | c.621G>A p.G207= | Silent (SNP) | VAF 96/310 reads (31%) | called by muse, mutect2, varscan2
- ARFGAP1 | c.835-165G>T | Intron (SNP) | VAF 54/201 reads (27%) | called by muse, mutect2, varscan2
- DNAJB14 | c.451+58C>G | Intron (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- ITPR1 | c.6907+1250G>A | Intron (SNP) | VAF 6/30 reads (20%) | catalogued as rs925546590; called by muse, varscan2
- MED26 | c.148-99G>A | Intron (SNP) | VAF 7/20 reads (35%) | catalogued as rs1002681549; called by muse, mutect2, varscan2
- MMP19 | c.*10del | 3'UTR (DEL) | VAF 6/57 reads (11%) | called by mutect2, varscan2
- NOL9 | c.881-14T>G | Intron (SNP) | VAF 35/196 reads (18%) | called by muse, mutect2, varscan2
- PLOD2 | c.-38G>A | 5'UTR (SNP) | VAF 30/134 reads (22%) | catalogued as rs781766778; called by muse, mutect2, varscan2
- SESN1 | c.-57C>A | 5'UTR (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- SLCO1A2 | c.1675+57T>G | Intron (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- TBC1D10B | c.-35C>T | 5'UTR (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- TUSC1 | c.*14C>T | 3'UTR (SNP) | VAF 63/157 reads (40%) | catalogued as rs1334173781; called by muse, mutect2, varscan2
